CCDI case PBCBLT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a2cf02a7-4063-4c5d-979f-0d47bbd10e24

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9473/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.9 years (1,422 days).

Biospecimens (3 samples)
- Sample 0DN9EI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN9EQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DN9EY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
